CCG case CUPP-B7RG — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8ea9ace1-11a1-421c-8ead-e5be7d20aab7

Demographics
Sex at birth: male; Race: native hawaiian or other pacific islander; Ethnicity: not hispanic or latino; Vital status: Dead; Days to death: 4,484 days (12.3 years); Year of death: 2011; Cause of death: Not Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C80.9; Tissue or organ of origin: Unknown primary site; Classification of tumor: primary; Year of diagnosis: 1999; Prior malignancy: no.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: First-Line Therapy.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy.

Follow-up (1 entry)
- Days to follow up: 4,484 days (12.3 years); Year of follow up: 2011.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B7RG-NT1-A: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample CUPP-B7RG-TTM1-A: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B7RG-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 64; Percent tumor nuclei: 32; Percent normal cells: 15; Percent necrosis: 1; Percent stromal cells: 20; Percent lymphocyte infiltration: 64; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
